MMRF case MMRF_1085 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d92b88aa-4160-49ed-b5a2-f0d7b06fd985

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 1,470 days (4.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.6 years (22,137 days); ISS stage: II; Days to last known disease status: 1,470 days (4.0 years); Days to last follow up: 1,470 days (4.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 211 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 212 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 217 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 308 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 316 days; Days to treatment end: 413 days (1.1 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 449 days (1.2 years); Days to treatment end: 841 days (2.3 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 870 days (2.4 years); Days to treatment end: 870 days (2.4 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 871 days (2.4 years); Days to treatment end: 871 days (2.4 years).
   Treatment given: Therapeutic agents: Bendamustine + Bortezomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,105 days (3.0 years); Days to treatment end: 1,162 days (3.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,182 days (3.2 years); Days to treatment end: 1,217 days (3.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,470.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 3.22 g/L; Immunoglobulin A 43.5 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 4.7 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 9.9 g/dL; Glucose 7.1 mmol/L; C-Reactive Protein 0.29 mg/dL.
- Day 106 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.26 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 9.4 g/L; Immunoglobulin A 2.08 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.54 mg/dL; Immunoglobulin G 5.06 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 253 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 5.13 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.1 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 37.1 g/L; Total Protein 6.4 g/dL; Glucose 6.55 mmol/L.
- Day 344 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 8.46 g/L; Immunoglobulin A 1.49 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 6.93 mmol/L.
- Day 435 (ECOG 1): M Protein 2.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 20.1 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.76 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 8.7 g/dL; Glucose 5.34 mmol/L.
- Day 533 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 5.56 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.28 µg/mL; Lactate Dehydrogenase 4.23 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 352 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 4.9 mmol/L.
- Day 618 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 5.23 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.41 µg/mL; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 5.72 mmol/L.
- Day 701 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 5.58 g/L; Immunoglobulin A 3.07 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.89 mmol/L.
- Day 785 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 4.32 g/L; Immunoglobulin A 4.15 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 6.33 mmol/L.
- Day 862 (ECOG 1): M Protein 3.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 287 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.56 mg/dL; Immunoglobulin G 2.1 g/L; Immunoglobulin A 39.4 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 6.37 µg/mL; Lactate Dehydrogenase 6.03 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 179 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.83 mmol/L; Albumin 24 g/L; Total Protein 9.4 g/dL; Glucose 6.77 mmol/L.
- Day 981 (ECOG 1): M Protein 6.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 0.95 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 37.5 g/L; Total Protein 6.8 g/dL; Glucose 5.61 mmol/L.
- Day 1,063 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 8.64 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 7.81 mmol/L.
- Day 1,162 (ECOG 1): M Protein 1.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 113 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.94 mg/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 13.9 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 8.2 g/dL; Glucose 5.56 mmol/L.
- Day 1,252 (ECOG 1): M Protein 3.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 2.54 g/L; Immunoglobulin A 39.3 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 5.02 mmol/L; Leukocytes 1.1 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 10 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.55 mmol/L; Albumin 25 g/L; Total Protein 9.9 g/dL; Glucose 8.47 mmol/L.
- Day 1,345 (ECOG 1): M Protein 5.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1967 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.43 mg/dL; Immunoglobulin G 2.36 g/L; Immunoglobulin A 58 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 4.77 mmol/L; Leukocytes 7.6 ×10⁹/L; Platelets 12 ×10⁹/L; Creatinine 693 µmol/L; Blood Urea Nitrogen 39.3 mmol/L; Calcium 2.08 mmol/L; Albumin 21 g/L; Total Protein 10.2 g/dL; Glucose 7.76 mmol/L.
- Day 1,388: Hemoglobin 4.28 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 35 ×10⁹/L; Creatinine 674 µmol/L; Blood Urea Nitrogen 27.1 mmol/L; Calcium 2.25 mmol/L; Albumin 22 g/L; Total Protein 9.1 g/dL; Glucose 7.65 mmol/L.

Other clinical attributes
- Day -13: Weight: 98 kg; Height: 173 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1085_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 253 days.
- Sample MMRF_1085_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 435 days (1.2 years).
